CCDI case PBCBGG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e217a20e-1549-4242-9dff-6f6da79a4d21

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.1 years (3,313 days).

Biospecimens (3 samples)
- Sample 0DNKZB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNKZH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DNKZL: Tissue type: Tumor; Specimen type: Solid Tissue.
